Somatic mutation profile of tumor specimen TCGA-EE-A29W-06A (aliquot TCGA-EE-A29W-06A-11D-A196-08) from TCGA case TCGA-EE-A29W, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.7 years (20,350 days).
Specimen TCGA-EE-A29W-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08365ff7-b67b-415d-8004-eea06b69700d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29W-10A (Blood Derived Normal), aliquot TCGA-EE-A29W-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ea3e977-167f-40a0-b8c0-bdfd2a1c11ac

The open-access MAF lists 88 somatic variants for this specimen: 62 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 25, Nonsense Mutation 5, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB5 | c.3686G>A p.G1229E (on ENST00000404938 / NM_001163941.2; = p.G784E on NM_178559.6) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51718587; called by muse, mutect2, varscan2
- ADGRA3 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs768058984, COSV51567252; called by muse, mutect2, varscan2
- AGBL5 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs762808695, COSV59937920; called by muse, varscan2
- ALPK3 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs867889252, COSV51938698; called by muse, varscan2
- ANKRD22 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.075); catalogued as COSV64235879; called by muse, mutect2, varscan2
- ARHGEF12 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs754670094, COSV63106913; called by muse, mutect2, varscan2
- BSN | c.10879G>C p.G3627R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV56525713; called by muse, mutect2, varscan2
- C7 | c.1543G>C p.G515R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57479431; called by mutect2, varscan2
- C8B | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV64776396, COSV64779166; called by muse, mutect2, varscan2
- CA9 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 14/16 reads (88%) | catalogued as COSV65676146; called by muse, mutect2
- CAMK1D | c.833G>A p.W278* | Nonsense Mutation (SNP) | VAF 80/131 reads (61%) | catalogued as COSV101124081, COSV66618357; called by muse, mutect2, varscan2
- CCDC116 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53042222; called by muse, mutect2, varscan2
- CD4 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.562); catalogued as COSV50589182; called by muse, mutect2
- CEP126 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs755303348, COSV54829619; called by muse, mutect2, varscan2
- CRH | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as COSV52542615; called by muse, mutect2, varscan2
- CSMD1 | c.4357G>A p.G1453R (on ENST00000520002; = p.G1452R on NM_033225.6) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59371199; called by muse, mutect2, varscan2
- CXorf21 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as COSV66762639; called by muse, mutect2, varscan2
- DDX59 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV58753658; called by muse, mutect2, varscan2
- DSEL | c.1558C>A p.Q520K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.985); catalogued as COSV59494002; called by muse, mutect2, varscan2
- EDDM3A | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV58795494; called by muse, mutect2, varscan2
- EDRF1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as COSV61764982; called by muse, mutect2, varscan2
- FASTKD5 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV53908787; called by muse, mutect2, varscan2
- FCRLB | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV61060457; called by muse, mutect2, varscan2
- GABRA6 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.78); PolyPhen benign (0.248); catalogued as COSV50890852; called by muse, mutect2, varscan2
- GHR | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV50125706; called by muse, mutect2, varscan2
- GPR37 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV58256200; called by muse, mutect2, varscan2
- HELZ2 | c.6862C>T p.R2288W (on ENST00000467148 / NM_001037335.2; = p.R1719W on NM_033405.3) | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs202204982, COSV64443192; called by muse, mutect2, varscan2
- HTR3B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1180582122, COSV52742593; called by muse, mutect2, varscan2
- ITGAV | c.1486A>C p.T496P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99654517; called by muse, mutect2, varscan2
- L2HGDH | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV55560044; called by muse, mutect2, varscan2
- LRP2 | c.11773C>T p.P3925S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV55569596; called by muse, mutect2, varscan2
- LSR | c.1268C>T p.P423L (on ENST00000361790; = p.P404L on NM_015925.6) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); catalogued as rs764830985, COSV55888007; called by muse, mutect2, varscan2
- MON1B | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV50252247; called by muse, mutect2
- MS4A1 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.914); catalogued as COSV61942896; called by mutect2, varscan2
- NEK4 | c.2278C>T p.H760Y | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV51782678; called by muse, mutect2, varscan2
- OR1D2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs767444459, COSV58921027; called by muse, mutect2, varscan2
- OR5C1 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV65456637; called by muse, mutect2, varscan2
- PCDHB10 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs189437073, COSV53379211; called by muse, mutect2, varscan2
- PENK | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1563485616, COSV59242881; called by muse, mutect2, varscan2
- PHKB | c.2641C>T p.H881Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV54531611; called by muse, mutect2, varscan2
- PITPNM2 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV54907208; called by muse, mutect2, varscan2
- PLA2G7 | c.893G>A p.W298* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV51264654; called by muse, mutect2, varscan2
- PLCL1 | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70866435; called by muse, mutect2, varscan2
- PPP6C | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 89/118 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65208884; called by muse, mutect2, varscan2
- PRB2 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs200440137; called by muse, varscan2
- PRSS8 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.495); catalogued as rs779657113, COSV54898589; called by muse, mutect2, varscan2
- PTPRC | c.1414A>T p.S472C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV61419380; called by muse, mutect2, varscan2
- RHOBTB1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV61959897; called by muse, mutect2
- ROS1 | c.3878C>T p.S1293F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV63855332; called by muse, mutect2
- RSPO1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV62975139; called by muse, mutect2, varscan2
- SEPTIN4 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.96); catalogued as rs140186503; called by muse, mutect2, varscan2
- SERPINB3 | c.61A>T p.K21* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV52193634; called by mutect2, varscan2
- SVIL | c.2687C>T p.T896I (on ENST00000355867 / NM_021738.3; = p.T470I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV63447237; called by muse, mutect2, varscan2
- SYCP2 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.838); catalogued as COSV62771703; called by muse, mutect2, varscan2
- TACSTD2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs774395222, COSV64666896; called by mutect2, varscan2
- TMF1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.265); catalogued as COSV68375586; called by muse, mutect2, varscan2
- WASF1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63936052; called by muse, mutect2, varscan2
- ZNF213 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs201631772, COSV67727700; called by mutect2, varscan2
- ZNF532 | c.111T>G p.H37Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60175109; called by muse, mutect2, varscan2
- DNM1L | c.2165del p.G722Efs*26 (on ENST00000549701 / NM_012062.5; = p.G685Efs*26 on NM_005690.4) | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- GNPTG | c.609+2dup p.X203_splice | Splice Site (INS) | VAF 20/36 reads (56%) | called by mutect2, pindel, varscan2
- A4GNT | c.210C>T p.S70= | Silent (SNP) | VAF 141/310 reads (45%) | catalogued as rs374392631, COSV52629894; called by muse, mutect2, varscan2
- ACTRT2 | c.94C>A p.R32= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV65759300, COSV65760271; called by mutect2, varscan2
- C6orf58 | c.900G>A p.V300= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100315050, COSV61667111; called by muse, mutect2, varscan2
- CLDN4 | c.357C>T p.I119= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs570729167, COSV99936377; called by muse, mutect2, varscan2
- CR2 | c.1896T>C p.S632= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV65509333; called by muse, mutect2, varscan2
- FAM214A | c.2034C>T p.S678= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV55926713; called by muse, mutect2, varscan2
- FRMD5 | c.310C>T p.L104= | Silent (SNP) | VAF 117/214 reads (55%) | catalogued as COSV68724801; called by muse, mutect2, varscan2
- GBX2 | c.705C>T p.S235= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs113681406, COSV60445545; called by mutect2, varscan2
- GLT6D1 | c.309C>T p.F103= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as rs772933599, COSV65628331; called by muse, mutect2, varscan2
- GLYATL2 | c.372G>A p.Q124= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV54851154; called by muse, mutect2, varscan2
- HMOX1 | c.222C>T p.F74= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs148073049; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNT1 | c.237G>A p.K79= (on ENST00000488444; = p.K98= on NM_020822.3) | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as COSV53708923; called by muse, mutect2, varscan2
- KNSTRN | c.96G>A p.R32= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV51103425; called by muse, mutect2, varscan2
- LRP2 | c.13401C>T p.L4467= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs762776652, COSV55547276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBNL1 | c.430C>T p.L144= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as COSV56834154; called by muse, mutect2, varscan2
- OR52M1 | c.96C>T p.P32= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs774573739, COSV64171898; called by muse, mutect2, varscan2
- PCDHAC2 | c.285G>A p.T95= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV53865524; called by muse, mutect2, varscan2
- PRKD2 | c.1830C>T p.I610= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs201126800, COSV52189139; called by muse, mutect2, varscan2
- SGSM1 | c.1065G>A p.K355= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV68512735; called by muse, mutect2, varscan2
- SLC38A10 | c.1698C>T p.A566= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV55848594; called by muse, mutect2
- SLC4A5 | c.2574C>T p.N858= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV61031886; called by muse, varscan2
- TBC1D19 | c.354C>T p.I118= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV53519345; called by muse, mutect2, varscan2
- TMEM74 | c.465G>A p.L155= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV52463809, COSV52464430; called by muse, mutect2, varscan2
- TMTC2 | c.768G>A p.S256= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs371809861; called by muse, mutect2, varscan2
- ZFP57 | c.159C>T p.F53= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV65306469, COSV65306834; called by muse, mutect2, varscan2
- LDB3 | c.689+3888C>T | Intron (SNP) | VAF 14/138 reads (10%) | catalogued as rs772657845, COSV99554914; called by muse, mutect2, varscan2
